Somatic mutation profile of tumor specimen TCGA-A6-2686-01A (aliquot TCGA-A6-2686-01A-01D-1408-10) from TCGA case TCGA-A6-2686, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 81.1 years (29,623 days).
Specimen TCGA-A6-2686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6180939-f32b-4fed-a824-34ef0dbefc21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2686-10A (Blood Derived Normal), aliquot TCGA-A6-2686-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71fbd3ed-d40b-4c45-9b6c-13ee6bf823aa

The open-access MAF lists 2,592 somatic variants for this specimen: 1,952 protein-altering or splice-affecting, 591 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,282, Silent 591, Frame Shift Del 410, Frame Shift Ins 98, Nonsense Mutation 82, In Frame Del 35, Splice Site 27, Intron 20, Splice Region 15, RNA 12, 3'UTR 7, 3'Flank 5.

Variants (750 of 2,592; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A3 | c.2305C>T p.R769C (on ENST00000545399 / NM_001256214.2; = p.R756C on NM_152296.5) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064797245; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA1A | c.3544del p.L1182Sfs*8 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CAPN3 | c.1322del p.G441Vfs*22 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs1555421871, CD991655, CM041740, COSV58821007; ClinVar: pathogenic; called by mutect2, pindel
- CTCF | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50461516; called by muse, mutect2, varscan2
- DAXX | c.1353_1355dup p.E457dup | In Frame Ins (INS) | VAF 6/22 reads (27%) | hotspot (GDC flag); catalogued as rs762240849; called by mutect2, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- EPCAM | c.491+1G>A p.X164_splice | Splice Site (SNP) | VAF 10/83 reads (12%) | catalogued as rs606231203, CS083989, COSV55392567; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1973G>A p.R658Q (on ENST00000281708 / NM_001349798.2; = p.R578Q on NM_018315.5) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs759610249, COSV55905466; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLA | c.718_719del p.K240Efs*9 | Frame Shift Del (DEL) | VAF 61/117 reads (52%) | catalogued as rs869312389; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KDM5C | c.2785C>T p.R929* | Nonsense Mutation (SNP) | VAF 17/27 reads (63%) | catalogued as rs782405999, COSV64765756; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.5290del p.E1764Kfs*27 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs1415944134, COSV101370451, COSV70355297; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 6/36 reads (17%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NF1 | c.2033del p.P678Rfs*10 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs587781807, CX1511110; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- OCA2 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144812594, CM952146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.2174+1G>A p.X725_splice | Splice Site (SNP) | VAF 24/129 reads (19%) | catalogued as rs267608172, CS083966, COSV56222103; ClinVar: pathogenic; called by mutect2, varscan2
- RBCK1 | c.1054C>T p.R352* (on ENST00000356286 / NM_031229.4; = p.R310* on NM_006462.6) | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as rs780854072, CM1313364, COSV100675876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN4A | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908556, CM043573, CM043574, COSV71127096; ClinVar: pathogenic; called by mutect2, varscan2
- SMAD2 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 24/44 reads (55%) | hotspot (GDC flag); catalogued as rs776149698, COSV50993232; called by muse, mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 28/56 reads (50%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TANGO2 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs199801224, COSV100530098; ClinVar: pathogenic; called by mutect2, varscan2
- TINF2 | c.1010del p.G337Efs*4 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs756029660; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 28/48 reads (58%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- A1BG | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV54052905; called by muse, mutect2, varscan2
- AADAC | c.933T>A p.Y311* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV51760918, COSV51761472; called by muse, mutect2, varscan2
- ABCA1 | c.1400del p.L467Wfs*41 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as COSV66064637; called by mutect2, pindel, varscan2
- ABCA2 | c.2710G>A p.V904M (on ENST00000614293; = p.V874M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV55801698; called by muse, mutect2, varscan2
- ABCA8 | c.524A>C p.E175A | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV99286280; called by muse, mutect2, varscan2
- ABCB6 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99522009; called by muse, varscan2
- ABCC2 | c.4147-1G>A p.X1383_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100966590, COSV64987913; called by muse, mutect2, varscan2
- ABCC5 | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99657139; called by muse, mutect2, varscan2
- ABCG1 | c.1689G>T p.Q563H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV100494319; called by muse, mutect2
- ABHD16A | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1029812510, COSV65452363; called by muse, mutect2, varscan2
- ABHD8 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99917301; called by muse, mutect2, varscan2
- AC008676.3 | c.328dup p.Q110Pfs*33 | Frame Shift Ins (INS) | VAF 15/38 reads (39%) | catalogued as rs749913841; called by pindel, varscan2
- AC011455.2 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.922); catalogued as rs541776059, COSV55498211; called by mutect2, varscan2
- AC011462.1 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as rs749876943, COSV99524612, COSV99524667; called by muse, mutect2, varscan2
- ACLY | c.1595C>A p.P532H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100709774; called by muse, mutect2, varscan2
- ACLY | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1555631680, COSV61252727; called by muse, mutect2, varscan2
- ACP3 | c.733T>C p.S245P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.923); catalogued as COSV60488001; called by muse, mutect2, varscan2
- ACSM4 | c.884A>G p.H295R | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101257226; called by muse, mutect2, varscan2
- ACTR1B | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs559419020, COSV56703216; called by muse, mutect2, varscan2
- ADAD1 | c.1576A>G p.K526E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.843); catalogued as rs776213843, COSV99635918; called by muse, mutect2, varscan2
- ADAD2 | c.865G>A p.A289T (on ENST00000315906 / NM_001145400.2; = p.A371T on NM_139174.4) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779661898, COSV51894029; called by muse, mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAMTS12 | c.2654G>T p.R885M | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100711285; called by muse, mutect2, varscan2
- ADAMTS4 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs751618429, COSV63490948; called by mutect2, varscan2
- ADAMTS7 | c.4249G>T p.A1417S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV101183160; called by muse, mutect2
- ADAR | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99426311; called by muse, mutect2, varscan2
- ADAR | c.285G>T p.R95S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV99426314; called by muse, mutect2, varscan2
- ADARB1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1450281854, COSV100653961; called by muse, mutect2, varscan2
- ADCK2 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.734); catalogued as rs1472841690, COSV99301708; called by muse, mutect2, varscan2
- ADCK5 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.36); catalogued as COSV100450576; called by muse, mutect2, varscan2
- ADCY2 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372631903, COSV100602382; called by muse, mutect2, varscan2
- ADCY5 | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100567957; called by muse, mutect2, varscan2
- ADCY5 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1175208636, COSV100567961; called by muse, mutect2, varscan2
- ADGRB3 | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV101001047; called by muse, mutect2, varscan2
- ADGRB3 | c.3470C>T p.A1157V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV99485904; called by muse, mutect2, varscan2
- ADGRF5 | c.3867G>T p.Q1289H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99345925; called by muse, mutect2
- ADGRL3 | c.522dup p.P175Sfs*9 (on ENST00000506720 / NM_001322402.2; = p.P107Sfs*9 on NM_015236.6) | Frame Shift Ins (INS) | VAF 48/127 reads (38%) | catalogued as rs1561047192; called by mutect2, pindel, varscan2
- ADPRS | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.606); catalogued as COSV99255561; called by muse, mutect2, varscan2
- ADRB3 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs953258922, COSV100799933; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs779815391; called by mutect2, varscan2
- AGRN | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs201787384, COSV101038942; called by muse, mutect2, varscan2
- AGRN | c.3065C>T p.S1022L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs777916390, COSV65072734; called by muse, mutect2, varscan2
- AHCTF1 | c.3380C>T p.S1127L (on ENST00000366508; = p.S1101L on NM_015446.5) | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs768661982, COSV58256153; called by muse, mutect2, varscan2
- AHRR | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327625; called by muse, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs778351035; called by mutect2, varscan2
- AKAP13 | c.4013C>A p.P1338H | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV63470599; called by muse, mutect2, varscan2
- AKAP5 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV57742840; called by muse, mutect2, varscan2
- AKAP9 | c.2121G>T p.Q707H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as COSV100662599; called by muse, mutect2, varscan2
- AKR7A3 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780744277, COSV64389285; called by muse, mutect2, varscan2
- AL136295.1 | c.2416C>T p.R806W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99938145; called by muse, mutect2, varscan2
- AL592490.1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV101308180, COSV69427411; called by muse, mutect2
- ALDH6A1 | c.1447T>C p.S483P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100620918; called by muse, varscan2
- ALDH8A1 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV99664835; called by muse, mutect2, varscan2
- ALDOC | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV52025988; called by muse, varscan2
- ALG10B | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs747047799, COSV100439933; called by muse, mutect2, varscan2
- ALG13 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 88/134 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs374290658, COSV99322575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH1 | c.202A>G p.N68D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99380667; called by muse, mutect2, varscan2
- ALKBH3 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776707628, COSV100236314, COSV57025074; called by muse, varscan2
- ALOX12B | c.406_408del p.E136del | In Frame Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs749617913; called by pindel, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALS2CL | c.982C>A p.L328M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.235); catalogued as COSV100015163; called by muse, mutect2, varscan2
- ALX4 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.072); catalogued as rs775689545, COSV100241142; called by muse, varscan2
- AMBN | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.713); catalogued as rs144829376; called by muse, mutect2, varscan2
- AMHR2 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99143353; called by muse, mutect2, varscan2
- ANK2 | c.2000A>G p.H667R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002561; called by muse, mutect2, varscan2
- ANK3 | c.3147G>T p.M1049I (on ENST00000280772 / NM_001320874.2; = p.M183I on NM_001149.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV55075407; called by muse, mutect2, varscan2
- ANK3 | c.1990G>A p.G664R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55075418; called by muse, mutect2, varscan2
- ANKFN1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100593777; called by muse, mutect2, varscan2
- ANKIB1 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs370944314, COSV99729404; called by muse, mutect2, varscan2
- ANKRD13A | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs769790065, COSV55676043; called by muse, mutect2, varscan2
- ANKRD27 | c.2610G>T p.Q870H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100042949; called by muse, mutect2, varscan2
- ANKRD30A | c.3226C>T p.Q1076* (on ENST00000611781; = p.Q1020* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 162/387 reads (42%) | catalogued as COSV100653874; called by muse, mutect2, varscan2
- ANKRD53 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs553903679, COSV55539050; called by muse, mutect2, varscan2
- ANO10 | c.974G>A p.C325Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV99428705; called by mutect2, varscan2
- ANO7 | c.1453G>A p.E485K (on ENST00000274979; = p.E431K on NM_001370694.2) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs780268640, COSV51468046; called by muse, mutect2, varscan2
- ANO9 | c.772-3del | Splice Region (DEL) | VAF 8/39 reads (21%) | catalogued as rs535142896; called by pindel, varscan2
- AOC1 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs766971033, COSV62868602, COSV62870832; called by muse, mutect2, varscan2
- AOC2 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs1308162195, COSV53200397; called by muse, mutect2, varscan2
- AP000721.1 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV100029292; called by muse, mutect2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs753324780, COSV52227333; called by mutect2, varscan2
- AP2A1 | c.1924G>T p.G642W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100756362; called by muse, mutect2
- AP3D1 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100642815; called by muse, mutect2, varscan2
- AP3M2 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs151272027; called by muse, mutect2, varscan2
- APBA2 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); catalogued as COSV101382197, COSV101382357; called by muse, mutect2, varscan2
- APBA2 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243950158, COSV101258187; called by muse, mutect2, varscan2
- APC | c.6023C>T p.A2008V | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99968770; called by muse, mutect2, varscan2
- APOA5 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs773214283, COSV57064516; called by muse, mutect2, varscan2
- APOA5 | c.466del p.E156Kfs*44 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as COSV57062647; called by mutect2, varscan2
- APOBEC4 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756203206, COSV58017650; called by muse, mutect2, varscan2
- APOF | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1468056031, COSV100028998, COSV58475203; called by muse, mutect2, varscan2
- APOL4 | c.466A>G p.I156V (on ENST00000352371 / NM_145660.2; = p.I153V on NM_030643.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100274147; called by muse, mutect2, varscan2
- APPL1 | c.1659-1G>A p.X553_splice | Splice Site (SNP) | VAF 15/28 reads (54%) | catalogued as COSV99897827; called by muse, mutect2, varscan2
- AR | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs865948546, COSV101018702; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARAF | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as rs1569319031, COSV51691372; called by muse, mutect2, varscan2
- ARAP1 | c.3860G>A p.R1287H (on ENST00000393609 / NM_001040118.2; = p.R1042H on NM_015242.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs747791198, COSV100502017; called by muse, mutect2, varscan2
- ARFGEF3 | c.5405G>A p.G1802D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.973); catalogued as COSV99294076, COSV99295106; called by muse, mutect2, varscan2
- ARHGAP10 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100331424; called by muse, varscan2
- ARHGAP10 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs145234400; called by muse, mutect2, varscan2
- ARHGAP11A | c.2111A>G p.H704R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.133); catalogued as COSV100276835; called by muse, mutect2
- ARHGAP22 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99985595; called by muse, mutect2
- ARHGAP25 | c.1094del p.P365Lfs*17 (on ENST00000409202 / NM_001007231.3; = p.P357Lfs*17 on NM_014882.3) | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs1004388629; called by mutect2, pindel, varscan2
- ARHGEF10 | c.1451C>T p.A484V (on ENST00000398564; = p.A459V on NM_014629.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs144726787; called by muse, varscan2
- ARHGEF40 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53883246; called by muse, mutect2, varscan2
- ARID1B | c.5334A>G p.I1778M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV51685602; called by muse, varscan2
- ARID2 | c.5360G>A p.R1787H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100536473; called by muse, mutect2, varscan2
- ARID3C | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as COSV99426960; called by muse, mutect2, varscan2
- ARL14 | c.229T>C p.C77R | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs762555229, COSV100296507; called by muse, mutect2, varscan2
- ARL2BP | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV99536001; called by muse, mutect2, varscan2
- ARL5B | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372696681; called by muse, mutect2, varscan2
- ARL6IP6 | c.132G>C p.E44D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV100424053; called by mutect2, varscan2
- ARMH4 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99958519; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs753865255; called by mutect2, varscan2
- ART1 | c.735dup p.F246Lfs*2 | Frame Shift Ins (INS) | VAF 5/10 reads (50%) | catalogued as rs762428866; called by mutect2, varscan2
- ASAH1 | c.504del p.G169Vfs*3 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as CM1511594, CS1411695; called by mutect2, pindel, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | catalogued as rs772181094; called by mutect2, varscan2
- ASAH2B | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as COSV99485921; called by muse, varscan2
- ASB17 | c.530dup p.N177Kfs*21 | Frame Shift Ins (INS) | VAF 27/66 reads (41%) | catalogued as rs749460467; called by mutect2, varscan2
- ASH1L | c.4504A>G p.M1502V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs138098710, COSV100853126; called by mutect2, varscan2
- ASIC3 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52525026; called by muse, mutect2, varscan2
- ASPM | c.8069G>A p.R2690Q | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs191126815, COSV54126839; called by muse, mutect2, varscan2
- ASXL2 | c.3534_3536del p.E1178del | In Frame Del (DEL) | VAF 50/122 reads (41%) | catalogued as rs774914918; called by pindel, varscan2
- ATAD5 | c.3131C>T p.S1044F | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs775048331, COSV100430054; called by muse, mutect2, varscan2
- ATF5 | c.255del p.G86Afs*32 | Frame Shift Del (DEL) | VAF 29/66 reads (44%) | catalogued as rs766479650; called by mutect2, pindel, varscan2
- ATG101 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as rs751591793, COSV100401058; called by muse, mutect2, varscan2
- ATG13 | c.1019C>T p.A340V (on ENST00000359513 / NM_001346321.1; = p.A303V on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); catalogued as COSV100365854; called by muse, mutect2, varscan2
- ATIC | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs766526084, COSV52694470, COSV99377762; called by muse, mutect2, varscan2
- ATP10A | c.3865A>G p.R1289G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1375175983, COSV100791375; called by muse, mutect2, varscan2
- ATP13A2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208175914, COSV58700970; called by muse, mutect2, varscan2
- ATP2A2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100428737; called by muse, mutect2, varscan2
- ATP2B2 | c.1063G>A p.E355K (on ENST00000352432; = p.E321K on NM_001683.5) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV59497812; called by muse, mutect2, varscan2
- ATP2B3 | c.3368G>A p.S1123N (on ENST00000263519 / NM_001001344.2; = p.*1174= on NM_021949.3) | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV54857901; called by muse, mutect2, varscan2
- ATP2C1 | c.1221G>T p.A407= | Splice Region (SNP) | VAF 53/163 reads (33%) | catalogued as COSV100146831, COSV60760913; called by muse, mutect2, varscan2
- ATRIP | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as rs758748581, COSV100202861; called by muse, mutect2, varscan2
- ATRIP | c.1744A>G p.R582G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1218193741, COSV99604087; called by muse, mutect2, varscan2
- ATXN1 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424319451, COSV55227671; called by muse, mutect2, varscan2
- ATXN2 | c.3587C>T p.A1196V (on ENST00000550104; = p.A1036V on NM_002973.4) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773079127, COSV57981143; called by muse, mutect2, varscan2
- ATXN2L | c.2584C>A p.P862T | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV100294693; called by muse, mutect2, varscan2
- ATXN7 | c.2546G>A p.S849N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55751668; called by muse, mutect2, varscan2
- AUTS2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1174650585, COSV100718244; called by muse, varscan2
- B3GALNT1 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs780802727, COSV100252075; called by muse, mutect2, varscan2
- B4GALNT1 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100247207; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | catalogued as COSV59620972; called by mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BAHCC1 | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs782310656, COSV57030794; called by muse, mutect2
- BAIAP3 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV60983027; called by muse, mutect2, varscan2
- BAIAP3 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766680413, COSV50104927; called by muse, mutect2, varscan2
- BARX2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs750583127, COSV104385911, COSV55649122; called by mutect2, varscan2
- BAZ2B | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs537143287, COSV58611117; called by mutect2, varscan2
- BCAT1 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs1410657525, COSV53916121; called by muse, varscan2
- BCL6 | c.1418del p.P473Rfs*117 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as COSV51655892; called by mutect2, pindel, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs754078059; called by mutect2, varscan2
- BCL9 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs142730791; called by muse, mutect2
- BCL9L | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as rs775991276, COSV52689083, COSV99419624; called by muse, mutect2, varscan2
- BCO2 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as rs1452226456, COSV63064500, COSV63065380; called by muse, varscan2
- BDKRB1 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs200342765, COSV53707427; called by muse, mutect2, varscan2
- BEGAIN | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV100766989; called by muse, mutect2, varscan2
- BHLHE22 | c.1130G>A p.C377Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100417835; called by muse, mutect2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 33/72 reads (46%) | catalogued as rs755506199; called by mutect2, varscan2
- BIN2 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as rs539014719, COSV57204534; called by muse, mutect2, varscan2
- BLOC1S2 | c.173-1G>T p.X58_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100705072; called by muse, mutect2, varscan2
- BLOC1S5 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs183115218; called by muse, mutect2, varscan2
- BMP5 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs144615410; called by muse, mutect2, varscan2
- BMP6 | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs752305807, COSV51664563; called by muse, varscan2
- BMPR1B | c.76del p.R26Vfs*31 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as COSV99215447; called by mutect2, varscan2
- BMPR2 | c.919T>C p.S307P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV101001567; called by muse, mutect2, varscan2
- BNC2 | c.3232C>T p.R1078* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV101036129, COSV101036391; called by muse, mutect2, varscan2
- BNC2 | c.2563G>A p.V855I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs747700365, COSV101032323; called by muse, mutect2, varscan2
- BOP1 | c.106del p.L36Sfs*154 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs782133829; called by mutect2, pindel, varscan2
- BORA | c.1005dup p.Y336Ifs*8 (on ENST00000613797; = p.Y261Ifs*8 on NM_024808.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | catalogued as rs757390268; called by mutect2, varscan2
- BPIFB1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99487483; called by muse, mutect2, varscan2
- BPIFB4 | c.911T>A p.V304D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100971573; called by muse, mutect2, varscan2
- BPTF | c.8590_8592del p.K2864del | In Frame Del (DEL) | VAF 12/92 reads (13%) | catalogued as rs1555683126; called by pindel, varscan2
- BRWD3 | c.2804G>A p.R935H | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100956255; called by muse, mutect2, varscan2
- BSN | c.3083G>A p.R1028H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762032784, COSV99608995; called by muse, mutect2, varscan2
- BTN3A2 | c.949del p.I317Sfs*4 | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | catalogued as COSV62687981; called by pindel, varscan2
- BTNL2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100896141; called by muse, mutect2, varscan2
- BTRC | c.815A>G p.Y272C (on ENST00000370187 / NM_033637.4; = p.Y236C on NM_003939.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64578680; called by muse, mutect2, varscan2
- BUB3 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.598); catalogued as COSV64364110; called by muse, mutect2, varscan2
- C10orf53 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100935070; called by muse, mutect2, varscan2
- C12orf45 | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV55013026; called by muse, mutect2, varscan2
- C14orf39 | c.179A>C p.E60A | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100407816; called by muse, mutect2, varscan2
- C14orf93 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99401070; called by muse, mutect2, varscan2
- C17orf64 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as rs768877828, COSV99293540; called by muse, mutect2, varscan2
- C19orf57 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as rs765683700, COSV100694757; called by muse, mutect2, varscan2
- C2CD2L | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.588); catalogued as COSV100371332; called by muse, mutect2, varscan2
- C2CD5 | c.955A>T p.M319L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.239); catalogued as COSV61726266; called by muse, mutect2, varscan2
- C2CD6 | c.1855del p.I619Lfs*19 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs752496395; called by mutect2, varscan2
- C2orf66 | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61099106; called by muse, mutect2, varscan2
- C5AR2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as rs150122288; called by muse, mutect2, varscan2
- C5AR2 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.62); catalogued as rs779835516, COSV99953806; called by muse, varscan2
- CA6 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV101077608; called by muse, mutect2, varscan2
- CACHD1 | c.3704dup p.Q1236Sfs*23 | Frame Shift Ins (INS) | VAF 12/71 reads (17%) | catalogued as rs764948820; called by mutect2, varscan2
- CACNA1A | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64195911; called by muse, mutect2, varscan2
- CACNA1D | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV55470944; called by muse, mutect2, varscan2
- CACNA1F | c.1668G>A p.W556* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100545067; called by muse, mutect2, varscan2
- CACNA1G | c.3062C>A p.A1021D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.065); catalogued as rs745410924, COSV61735355; called by mutect2, varscan2
- CACNA1H | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100673114; called by muse, mutect2, varscan2
- CACNA1H | c.5224G>A p.V1742M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100673116; called by muse, mutect2, varscan2
- CACNA2D2 | c.2503C>T p.R835C (on ENST00000479441 / NM_001174051.3; = p.R828C on NM_006030.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs774552132, COSV56567796; called by muse, mutect2, varscan2
- CADM3 | c.1000G>A p.G334S (on ENST00000368125 / NM_001127173.3; = p.G368S on NM_021189.5) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1224156115, COSV100929801, COSV100929922; called by muse, mutect2, varscan2
- CADPS | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.01); catalogued as rs1181909351; called by mutect2, varscan2
- CAMSAP3 | c.3263G>A p.R1088H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs754308415, COSV50335834; called by muse, mutect2, varscan2
- CAMTA1 | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767725186, COSV100351215, COSV57887081; called by muse, mutect2, varscan2
- CAMTA1 | c.1946C>T p.T649M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs772421310, COSV100351217; called by muse, mutect2, varscan2
- CAND1 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV73389786; called by muse, mutect2, varscan2
- CAPN12 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs368380755; called by muse, mutect2, varscan2
- CARD8 | c.694G>A p.G232S (on ENST00000651546 / NM_001184900.3; = p.G182S on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370395701; called by muse, mutect2, varscan2
- CARMIL2 | c.2657G>T p.S886I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV100576138; called by muse, mutect2, varscan2
- CARNS1 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100322129; called by muse, mutect2
- CASP10 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV53780051; called by muse, mutect2, varscan2
- CASQ1 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1190358351, COSV100927323; called by muse, mutect2, varscan2
- CATSPER4 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534133361, COSV58794308, COSV58794663; called by muse, mutect2, varscan2
- CAVIN3 | c.53del p.G18Vfs*6 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs751428461; called by mutect2, pindel, varscan2
- CAVIN4 | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV56867977; called by muse, mutect2, varscan2
- CC2D1A | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs773188635, COSV58780974; called by muse, mutect2, varscan2
- CC2D1A | c.2693del p.G898Vfs*45 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs1423002835; called by mutect2, pindel, varscan2
- CC2D1B | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs767027536, COSV99430073; called by mutect2, varscan2
- CCDC117 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.127); catalogued as COSV99968900; called by muse, mutect2, varscan2
- CCDC15 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as rs201773360; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC8 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100282098; called by muse, mutect2, varscan2
- CCL27 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs754147532, COSV99426535; called by muse, mutect2, varscan2
- CCNB2 | c.872T>C p.M291T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV99879092; called by muse, mutect2
- CCNC | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs755107219, COSV58334319; called by mutect2, varscan2
- CCP110 | c.2257T>G p.F753V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as COSV101195302; called by muse, mutect2, varscan2
- CCR1 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99946747; called by muse, mutect2, varscan2
- CCZ1 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 29/303 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58075089; called by muse, mutect2, varscan2
- CD151 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs534240443, COSV100431837; called by muse, mutect2, varscan2
- CD163 | c.2499G>T p.E833D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100775972; called by muse, mutect2, varscan2
- CD163L1 | c.2406G>A p.M802I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV100550311; called by muse, mutect2, varscan2
- CD300LG | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.536); catalogued as rs184299869; called by muse, mutect2, varscan2
- CD38 | c.473C>A p.T158K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV99882843; called by muse, mutect2, varscan2
- CD93 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as COSV55663893, COSV55669272; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC20B | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV57053084, COSV99697114; called by muse, mutect2, varscan2
- CDC42BPB | c.1847G>T p.R616L | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100775510; called by muse, mutect2, varscan2
- CDC42BPG | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.989); catalogued as rs1395165915, COSV100712115; called by muse, mutect2
- CDC42EP1 | c.289dup p.R97Pfs*78 | Frame Shift Ins (INS) | VAF 24/60 reads (40%) | catalogued as rs762035931; called by mutect2, varscan2
- CDC45 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV54243148, COSV54247743; called by muse, mutect2
- CDCP2 | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs544962128, COSV100313347, COSV61282441; called by mutect2, varscan2
- CDH16 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs558954232, COSV100233686, COSV100233976; called by muse, mutect2, varscan2
- CDH18 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as COSV56951035; called by muse, mutect2, varscan2
- CDH5 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV100439312; called by muse, mutect2, varscan2
- CELA2A | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100657581; called by muse, mutect2, varscan2
- CELA3A | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV99266610; called by muse, mutect2, varscan2
- CELF5 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV53014341; called by muse, mutect2
- CELSR2 | c.8524_8526del p.K2842del | In Frame Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs756748774; called by pindel, varscan2
- CELSR3 | c.9504G>C p.Q3168H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.556); catalogued as COSV99374065; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 70/219 reads (32%) | catalogued as rs1325731082; called by mutect2, varscan2
- CENPV | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.464); catalogued as rs778078087, COSV55333443; called by mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs769310263; called by mutect2, pindel, varscan2
- CEP135 | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779689049, COSV57260114; called by muse, mutect2, varscan2
- CEP162 | c.1709A>G p.K570R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100003005; called by muse, mutect2, varscan2
- CEP162 | c.1177A>G p.N393D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV100003009; called by muse, varscan2
- CEP162 | c.670dup p.I224Nfs*16 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | catalogued as rs757565766; called by mutect2, pindel, varscan2
- CEP164 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs772164945, COSV99633751, COSV99634726; called by muse, mutect2, varscan2
- CEP170 | c.3455A>G p.Q1152R | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100317363; called by muse, mutect2
- CEP170 | c.1983G>T p.K661N | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as rs762554071, COSV60506702; called by muse, mutect2, varscan2
- CEP78 | c.2027G>A p.S676N (on ENST00000424347 / NM_001349840.2; = p.S677N on NM_032171.3) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99450665; called by muse, mutect2, varscan2
- CEP89 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 140/418 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.073); catalogued as COSV59866820; called by muse, mutect2, varscan2
- CER1 | c.507+2T>C p.X169_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV101097886; called by mutect2, varscan2
- CFAP251 | c.2193G>T p.W731C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99996245; called by muse, mutect2, varscan2
- CFAP410 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100297181; called by muse, mutect2, varscan2
- CFHR3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV66403023; called by muse, mutect2, varscan2
- CHCHD4 | c.274C>T p.R92W (on ENST00000396914 / NM_001098502.2; = p.R105W on NM_144636.3) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); catalogued as rs773338809, COSV55500256; called by muse, mutect2, varscan2
- CHD6 | c.4622G>A p.R1541H | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777741378, COSV64694080; called by muse, mutect2, varscan2
- CHD7 | c.6953A>G p.N2318S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV101418320; called by muse, mutect2, varscan2
- CHD8 | c.6082C>T p.H2028Y (on ENST00000646647 / NM_001170629.2; = p.H1749Y on NM_020920.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV100765332; called by muse, mutect2, varscan2
- CHD8 | c.5882G>A p.R1961H (on ENST00000646647 / NM_001170629.2; = p.R1682H on NM_020920.4) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs1338591756, COSV100765333; called by muse, mutect2, varscan2
- CHEK2 | c.721+2T>C p.X241_splice (on ENST00000382580 / NM_001005735.2; = p.X198_splice on NM_007194.4) | Splice Site (SNP) | VAF 63/132 reads (48%) | catalogued as COSV60418362; called by muse, mutect2, varscan2
- CHMP1A | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV99498459; called by muse, mutect2, varscan2
- CHRNA4 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1349610263, COSV64717784; called by muse, mutect2
- CHRNB2 | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV100872625; called by muse, mutect2, varscan2
- CHST14 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs1173231334, COSV100087006; called by muse, mutect2
- CHST2 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.125); catalogued as COSV58886737; called by muse, mutect2, varscan2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as COSV50671496; called by mutect2, pindel, varscan2
- CIZ1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.339); catalogued as COSV99476952; called by muse, mutect2, varscan2
- CLASP1 | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99755660; called by muse, mutect2, varscan2
- CLASRP | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV55512350; called by muse, mutect2, varscan2
- CLCN5 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV65800413; called by muse, mutect2, varscan2
- CLDN25 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746964341, COSV101493608; called by muse, mutect2, varscan2
- CLEC6A | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV65987978; called by muse, mutect2, varscan2
- CLGN | c.656del p.K219Sfs*14 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | catalogued as COSV57773501; called by mutect2, pindel, varscan2
- CLIC2 | c.57G>A p.K19= | Splice Region (SNP) | VAF 24/127 reads (19%) | catalogued as COSV100425645, COSV100425716; called by muse, mutect2, varscan2
- CLIP1 | c.1739G>A p.R580Q (on ENST00000620786 / NM_001247997.1; = p.R569Q on NM_002956.2) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1050623431, COSV56804315; called by muse, mutect2, varscan2
- CLIP3 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100859341; called by mutect2, varscan2
- CMKLR1 | c.283C>A p.H95N (on ENST00000312143 / NM_001142344.2; = p.H93N on NM_004072.3) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100379510; called by muse, mutect2, varscan2
- CMTR2 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1567504539, COSV57603779; called by mutect2, varscan2
- CNBD2 | c.717-1G>T p.X239_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100839129; called by muse, mutect2, varscan2
- CNGB1 | c.3551C>T p.P1184L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV99204009; called by muse, mutect2, varscan2
- CNN1 | c.711C>A p.H237Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV52948118; called by muse, mutect2, varscan2
- CNNM1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as COSV63203115; called by muse, mutect2, varscan2
- CNNM4 | c.1496T>C p.V499A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100998721; called by muse, mutect2, varscan2
- CNOT1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs367777689; called by muse, mutect2, varscan2
- CNOT3 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs1232022938, COSV99652084; called by muse, mutect2, varscan2
- CNTN1 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100751588; called by muse, mutect2, varscan2
- CNTN2 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332573662, COSV100085221; called by muse, mutect2, varscan2
- CNTN5 | c.1193A>G p.D398G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99678606; called by muse, mutect2, varscan2
- CNTN6 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100611159; called by muse, mutect2, varscan2
- CNTNAP3 | c.2944del p.V982Sfs*29 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as rs763585044, COSV52668218; called by mutect2, pindel, varscan2
- CNTRL | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53051902; called by muse, mutect2, varscan2
- COIL | c.485del p.N162Tfs*47 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | catalogued as rs769265872; called by mutect2, varscan2
- COL11A1 | c.5206G>T p.G1736* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV62192692; called by muse, mutect2, varscan2
- COL17A1 | c.1170del p.E391Kfs*12 | Frame Shift Del (DEL) | VAF 64/182 reads (35%) | catalogued as rs769586532; called by mutect2, pindel, varscan2
- COL18A1 | c.3752G>T p.R1251M (on ENST00000359759 / NM_130444.3; = p.R1016M on NM_030582.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV100645359; called by muse, mutect2, varscan2
- COL1A1 | c.910del p.R304Vfs*237 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | catalogued as COSV56803507; called by mutect2, pindel, varscan2
- COL2A1 | c.4381C>A p.P1461T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99873483; called by muse, mutect2, varscan2
- COL4A6 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100564473; called by muse, mutect2
- COL5A1 | c.3125G>A p.G1042D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100880139; called by muse, varscan2
- COL5A1 | c.4043G>C p.G1348A | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1060502252, COSV65665157; ClinVar: uncertain significance; called by mutect2, varscan2
- COL6A2 | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs777354703, COSV99384728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS5 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs138638780; called by muse, mutect2, varscan2
- CORIN | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs571162211, COSV56687593; called by muse, mutect2, varscan2
- CORO1A | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs763606361, COSV54631494; called by muse, mutect2, varscan2
- CORO7 | c.2685G>T p.E895D | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1311544534, COSV99227845; called by muse, mutect2, varscan2
- COX5A | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs746397506, COSV59279218; called by muse, mutect2, varscan2
- CRACR2B | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58990733; called by muse, mutect2
- CREB3 | c.376_378del p.E126del | In Frame Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs769225730; called by pindel, varscan2
- CREBBP | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52120438, COSV52140220; called by muse, mutect2, varscan2
- CROCC | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs745994746, COSV100978305; called by mutect2, varscan2
- CROCC | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV100978306; called by muse, mutect2, varscan2
- CROT | c.1184A>G p.Q395R | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as rs1044669227, COSV100519580; called by muse, mutect2, varscan2
- CRTC2 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs377025190; called by muse, mutect2, varscan2
- CRYBG3 | c.7612C>T p.Q2538* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as rs1280731433, COSV99477165; called by muse, mutect2, varscan2
- CRYZ | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1042277419, COSV61718437; called by muse, mutect2, varscan2
- CS | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60834419; called by muse, mutect2, varscan2
- CSDC2 | c.38del p.P13Rfs*101 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV53448605; called by mutect2, pindel, varscan2
- CSMD1 | c.6115A>G p.S2039G (on ENST00000520002; = p.S2038G on NM_033225.6) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV100150298; called by muse, mutect2, varscan2
- CSMD1 | c.4466T>C p.V1489A (on ENST00000520002; = p.V1488A on NM_033225.6) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100150301; called by muse, mutect2, varscan2
- CSNK1A1L | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.093); catalogued as rs1405552303, COSV65790043; called by muse, mutect2, varscan2
- CSTF3 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60609550; called by muse, mutect2, varscan2
- CTBP2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100456625; called by muse, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTSB | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100565918; called by muse, mutect2, varscan2
- CTSC | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57059936, COSV99910789; called by muse, mutect2, varscan2
- CTSC | c.189del p.V64* | Frame Shift Del (DEL) | VAF 11/22 reads (50%) | catalogued as rs766504984; called by mutect2, varscan2
- CUL5 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV101263714; called by muse, mutect2, varscan2
- CXCL6 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1276498230, COSV99884960; called by muse, mutect2, varscan2
- CXCR2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100579007; called by muse, mutect2, varscan2
- CXorf38 | c.427A>T p.N143Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59948093; called by muse, mutect2, varscan2
- CYGB | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1287701626, COSV99506187; called by muse, mutect2, varscan2
- CYLC2 | c.78del p.K26Nfs*36 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs777849652; called by mutect2, pindel, varscan2
- CYP19A1 | c.610T>G p.L204V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99547844; called by muse, mutect2, varscan2
- CYTH2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); catalogued as rs368161948; called by muse, mutect2, varscan2
- DAAM1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759856885, CM154571, COSV100658513; called by muse, mutect2, varscan2
- DARS2 | c.905A>G p.Q302R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.051); catalogued as rs1173367549, COSV53408494; called by muse, mutect2, varscan2
- DBF4B | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | catalogued as COSV100154575; called by muse, mutect2, varscan2
- DCAF10 | c.940T>A p.L314M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54290226; called by muse, mutect2, varscan2
- DCAF12L2 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100758677; called by muse, mutect2, varscan2
- DCBLD2 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58788905; called by muse, mutect2
- DCLK3 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as rs373984062; called by muse, mutect2, varscan2
- DCLRE1A | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs200392207; called by muse, mutect2, varscan2
- DCST2 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.012); catalogued as rs778569738, COSV99421328; called by mutect2, varscan2
- DDAH2 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV101007521; called by muse, mutect2, varscan2
- DDRGK1 | c.297C>A p.A99= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100621472; called by muse, mutect2, varscan2
- DDX11 | c.1876-1G>T p.X626_splice | Splice Site (SNP) | VAF 14/192 reads (7%) | catalogued as COSV99299887; called by muse, mutect2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX23 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.973); catalogued as rs746790866, COSV57285669; called by muse, mutect2, varscan2
- DENND2B | c.2966C>A p.P989H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567605, COSV100567692; called by muse, mutect2, varscan2
- DENND2B | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs372527362, COSV58202891; called by mutect2, varscan2
- DENND3 | c.3373T>G p.C1125G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV99371226, COSV99371244; called by muse, mutect2, varscan2
- DENND6A | c.1087C>A p.Q363K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.644); catalogued as COSV100231552; called by muse, mutect2, varscan2
- DES | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770258461, COSV100900481; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DHX29 | c.3100C>A p.L1034I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99287446; called by muse, mutect2, varscan2
- DHX30 | c.464G>A p.R155H (on ENST00000445061 / NM_138615.3; = p.R116H on NM_014966.3) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.232); catalogued as rs139889547; called by muse, mutect2, varscan2
- DHX36 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773134906, COSV57671550; called by muse, mutect2, varscan2
- DHX57 | c.3190G>A p.V1064M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs149500475; called by muse, mutect2, varscan2
- DLG1 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1026224891, COSV100015581; called by muse, mutect2, varscan2
- DLG2 | c.2306G>A p.G769D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99717309; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs762874947; called by mutect2, varscan2
- DLK2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99767545; called by muse, mutect2, varscan2
- DMPK | c.1768T>C p.S590P | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1350246465, COSV99353389; called by muse, mutect2, varscan2
- DMRT3 | c.1091A>G p.Q364R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV99505958; called by muse, mutect2, varscan2
- DMRTC2 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54187548; called by muse, mutect2, varscan2
- DNAAF3 | c.661G>A p.G221R (on ENST00000524407 / NM_001256715.2; = p.G268R on NM_178837.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1302666486, COSV100787956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.1279G>A p.A427T (on ENST00000409039; = p.A366T on NM_207437.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs762780876, COSV101292373; called by muse, mutect2, varscan2
- DNAH10 | c.1670C>T p.T557M (on ENST00000409039; = p.T496M on NM_207437.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs778967410, COSV68987611; called by muse, mutect2, varscan2
- DNAH10 | c.5692G>A p.G1898S (on ENST00000409039; = p.G1837S on NM_207437.3) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377526922; called by muse, mutect2
- DNAH17 | c.13294C>T p.R4432C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149800703, COSV53147821; called by muse, mutect2, varscan2
- DNAH2 | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99318312; called by muse, mutect2, varscan2
- DNAH5 | c.13153C>T p.P4385S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV99451410; called by muse, mutect2, varscan2
- DNAH6 | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99407474; called by muse, mutect2, varscan2
- DNAH9 | c.5165G>A p.C1722Y | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99306644; called by muse, mutect2, varscan2
- DNAI2 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200358267; called by muse, mutect2, varscan2
- DNAJB12 | c.778C>T p.R260C (on ENST00000338820; = p.R226C on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs762040042, COSV58761364; called by mutect2, varscan2
- DNAJC10 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as rs776207150, COSV51137461; called by muse, mutect2, varscan2
- DNAJC11 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs146449481; called by muse, varscan2
- DNASE2 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as COSV99322450; called by muse, mutect2, varscan2
- DNER | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749718515, COSV59177639; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOK4 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs147737584; called by mutect2, varscan2
- DOP1B | c.2541dup p.G848Wfs*77 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs750520568; called by mutect2, varscan2
- DOP1B | c.4528G>A p.A1510T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs752976756, COSV101215571; called by mutect2, varscan2
- DPP9 | c.32G>A p.R11Q (on ENST00000598800; = p.R40Q on NM_139159.5) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs979420846, COSV99506108; called by muse, mutect2, varscan2
- DPYSL3 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100575222; called by muse, mutect2, varscan2
- DSCAM | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs762902524, COSV68021000, COSV68034391; called by muse, mutect2, varscan2
- DSCAML1 | c.732C>G p.I244M (on ENST00000321322; = p.I184M on NM_020693.4) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100356420; called by muse, mutect2, varscan2
- DTX2 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV100184705; called by muse, mutect2, varscan2
- DUOX1 | c.3872G>T p.R1291L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100368145; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 46/107 reads (43%) | catalogued as rs746928635; called by mutect2, varscan2
- DVL2 | c.1546C>A p.L516I | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV99138605; called by muse, mutect2
- E2F3 | c.877A>T p.N293Y | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100686075; called by muse, mutect2, varscan2
- E2F4 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.827); catalogued as rs376202405; called by muse, varscan2
- E2F7 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1159833657, COSV100523644; called by muse, mutect2, varscan2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 21/60 reads (35%) | catalogued as rs752987091; called by mutect2, varscan2
- EEA1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV100468003; called by muse, mutect2, varscan2
- EFCAB5 | c.2487A>T p.E829D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV100300434; called by muse, mutect2, varscan2
- EFCAB6 | c.722A>G p.N241S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.088); catalogued as rs768721041, COSV53069852; called by muse, mutect2, varscan2
- EFEMP1 | c.1016A>G p.E339G | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs779708532, COSV100816896; called by mutect2, varscan2
- EFHC1 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV64135908; called by muse, mutect2, varscan2
- EGR3 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100416221; called by muse, mutect2, varscan2
- EGR3 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs1563183488, COSV57834239; called by muse, varscan2
- EIF2AK4 | c.4669C>T p.R1557* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as rs372637398; called by muse, mutect2, varscan2
- EIF4G1 | c.3265G>T p.G1089W (on ENST00000346169 / NM_198241.3; = p.G894W on NM_004953.5) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100072022; called by muse, mutect2, varscan2
- EIF5B | c.1381A>G p.K461E | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); catalogued as COSV99177422; called by muse, mutect2, varscan2
- EIF5B | c.3362_3363del p.Q1121Rfs*13 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1374370597; called by mutect2, pindel
- ELAPOR1 | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100884732; called by muse, mutect2, varscan2
- ELAVL1 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV60965919; called by muse, mutect2, varscan2
- ELF1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV99523152; called by muse, mutect2, varscan2
- ELP1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749382362, COSV101010434; called by muse, mutect2, varscan2
- EMILIN1 | c.1353dup p.L452Afs*57 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | catalogued as rs763633527; called by mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs770453803; called by mutect2, varscan2
- EML5 | c.4252C>A p.L1418M (on ENST00000380664; = p.L1426M on NM_183387.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV100715892; called by muse, mutect2, varscan2
- ENAH | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781433637, COSV52865362, COSV99491026; called by muse, mutect2, varscan2
- ENKUR | c.312T>A p.N104K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100482169; called by muse, mutect2, varscan2
- ENO3 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52778711; called by muse, mutect2, varscan2
- ENOX2 | c.445G>A p.E149K (on ENST00000338144 / NM_001382520.1; = p.E120K on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as rs747944133, COSV100584325, COSV57656535; called by muse, mutect2, varscan2
- ENPEP | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); catalogued as rs1479797942, COSV54449676; called by muse, mutect2, varscan2
- EPCAM | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs766626946, COSV55394223; called by muse, mutect2, varscan2
- EPHA10 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs1200186933, COSV60404971; called by muse, mutect2, varscan2
- EPHB2 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs371215652; called by muse, mutect2, varscan2
- EPHB6 | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV101235984; called by muse, mutect2, varscan2
- EPPK1 | c.3364C>A p.L1122I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV73260916, COSV73262254; called by muse, mutect2, varscan2
- EPS8L1 | c.1771G>A p.E591K (on ENST00000201647 / NM_133180.3; = p.E464K on NM_017729.3) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs200225675, COSV52385182; called by muse, mutect2, varscan2
- ERICH3 | c.1536dup p.S513Ifs*2 | Frame Shift Ins (INS) | VAF 57/142 reads (40%) | catalogued as rs769157627; called by mutect2, pindel, varscan2
- ESPL1 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 45/114 reads (39%) | catalogued as rs1201326649, COSV99228900; called by muse, mutect2, varscan2
- ESPL1 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.476); catalogued as COSV99229484; called by muse, mutect2
- ESPL1 | c.3050T>G p.L1017R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99229485; called by muse, mutect2, varscan2
- ESPNL | c.823del p.L275Sfs*16 | Frame Shift Del (DEL) | VAF 31/64 reads (48%) | catalogued as rs1309653898; called by mutect2, pindel, varscan2
- ETNPPL | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99625446; called by muse, mutect2, varscan2
- EVC2 | c.2881G>A p.G961R | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV100186310; called by muse, mutect2, varscan2
- EVX2 | c.230T>C p.F77S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as COSV100420741; called by muse, mutect2, varscan2
- EWSR1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs772636858, COSV100132071, COSV58421516; called by mutect2, varscan2
- EXOC4 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV99554560; called by muse, mutect2
- EXOSC7 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs140459270; called by muse, mutect2, varscan2
- EXT1 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as CD087953, COSV100984091; called by muse, mutect2, varscan2
- EYA2 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs142696386; called by muse, mutect2, varscan2
- F2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs775306348, COSV100319587; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM160B1 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV100985172; called by muse, mutect2, varscan2
- FAM166A | c.558del p.A187Pfs*8 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs766839703; called by mutect2, pindel
- FAM20A | c.907_908del p.S303Cfs*76 | Frame Shift Del (DEL) | VAF 17/105 reads (16%) | catalogued as rs750880244; called by pindel, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 36/70 reads (51%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel, varscan2
- FAM47B | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs965258921, COSV61453604, COSV61457316; called by muse, mutect2, varscan2
- FAM47C | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.8); catalogued as rs1433951072, COSV63727228, COSV63729490; called by muse, mutect2, varscan2
- FAM83B | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs376026026; called by muse, mutect2, varscan2
- FAM83E | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.141); catalogued as rs756248260, COSV52374594; called by muse, mutect2, varscan2
- FASTKD5 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs547200037, COSV99418200; called by muse, mutect2, varscan2
- FAT1 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); catalogued as COSV101499446; called by muse, mutect2, varscan2
- FAT3 | c.12473T>C p.I4158T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53158317; called by muse, mutect2, varscan2
- FAT4 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV101272513; called by muse, mutect2, varscan2
- FAT4 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.215); catalogued as COSV67880909; called by muse, mutect2, varscan2
- FAXDC2 | c.846-1G>T p.X282_splice | Splice Site (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100303900; called by muse, mutect2
- FBLN5 | c.1117C>A p.R373S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM113495, COSV50907168; called by muse, mutect2
- FBN3 | c.4778G>A p.G1593D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs776245960, COSV99561313; called by muse, mutect2, varscan2
- FBN3 | c.2654G>A p.C885Y | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561315; called by muse, mutect2, varscan2
- FBXO40 | c.665T>C p.F222S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100573226; called by muse, mutect2, varscan2
- FBXO48 | c.324T>A p.N108K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100376821; called by muse, mutect2, varscan2
- FBXW4 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs148012023; called by muse, mutect2, varscan2
- FBXW8 | c.401G>A p.R134H (on ENST00000309909; = p.R172H on NM_012174.1) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs758915610, COSV99997805; called by muse, mutect2, varscan2
- FCGBP | c.5893G>A p.A1965T | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV55458520; called by muse, mutect2, varscan2
- FCHO2 | c.1789A>G p.R597G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV59276179; called by muse, mutect2
- FCN3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs746300270, COSV99585445; called by mutect2, varscan2
- FCSK | c.991T>C p.S331P | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.399); catalogued as COSV99851062; called by muse, mutect2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs748969702; called by mutect2, varscan2
- FGD3 | c.367del p.Q123Rfs*51 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs777351004, COSV100490512; called by mutect2, pindel, varscan2
- FGD6 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as rs1480726457, COSV59694011; called by muse, mutect2, varscan2
- FGF17 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV63925797; called by muse, mutect2, varscan2
- FGG | c.1278C>G p.H426Q | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100271948; called by muse, mutect2, varscan2
- FHOD3 | c.2137C>A p.L713I (on ENST00000359247 / NM_001281739.3; = p.L730I on NM_025135.5) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV99941720; called by muse, mutect2, varscan2
- FKBP10 | c.1333G>T p.G445C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99505256; called by muse, varscan2
- FKBP15 | c.3100T>C p.S1034P | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV53038351; called by muse, mutect2, varscan2
- FKBP4 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99133835; called by muse, mutect2, varscan2
- FKBP4 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs766636474, COSV99133837; called by muse, mutect2, varscan2
- FKRP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV59359814; called by muse, mutect2, varscan2
- FLNB | c.4603A>G p.S1535G | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99913823; called by muse, mutect2, varscan2
- FLRT2 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs769370773, COSV58138769; called by muse, mutect2, varscan2
- FMO3 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63006968, COSV63007633; called by muse, mutect2
- FN1 | c.2137G>T p.G713* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100117491; called by muse, mutect2, varscan2
- FNDC3B | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100394412; called by muse, mutect2, varscan2
- FNDC3B | c.3475G>T p.G1159W | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100394414; called by muse, mutect2, varscan2
- FNTB | c.1047dup p.L350Afs*4 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | catalogued as rs768774237; called by mutect2, varscan2
- FOLH1 | c.1501del p.S501Vfs*12 | Frame Shift Del (DEL) | VAF 19/154 reads (12%) | catalogued as rs764290022, COSV57049642; called by mutect2, pindel, varscan2
- FOXD4L6 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.837); catalogued as rs763388402; called by muse, mutect2, varscan2
- FOXE1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777292713, COSV100909951; called by muse, mutect2, varscan2
- FOXF1 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568384890, COSV99296598; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FOXP2 | c.1622T>A p.F541Y | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100647001; called by muse, mutect2, varscan2
- FOXRED1 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55008395; called by muse, mutect2, varscan2
- FREM2 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV99749406; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs752538869; called by pindel, varscan2
- FRY | c.4963A>G p.S1655G | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100969511; called by mutect2, varscan2
- FSD2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100575207; called by muse, mutect2, varscan2
- FUNDC2 | c.513_515del p.K171del | In Frame Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs782104310; called by pindel, varscan2
- FURIN | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs201334295, COSV99184670; called by mutect2, varscan2
- FXR1 | c.1507C>A p.R503S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs867278516, COSV99976486; called by muse, varscan2
- FYB2 | c.1387T>C p.C463R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.295); catalogued as rs1433128570, COSV100599618; called by muse, mutect2
- FYN | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99992019; called by muse, mutect2, varscan2
- FZD3 | c.888dup p.T297Yfs*25 | Frame Shift Ins (INS) | VAF 11/63 reads (17%) | catalogued as rs765036679; called by mutect2, varscan2
- GABRA1 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50114653; called by muse, mutect2, varscan2
- GABRE | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as COSV64820888; called by muse, mutect2, varscan2
- GALNT11 | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100231905; called by mutect2, varscan2
- GALNT15 | c.1393-2A>C p.X465_splice | Splice Site (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100327775; called by muse, mutect2, varscan2
- GALNT17 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV61150667; called by muse, mutect2, varscan2
- GALR2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.047); catalogued as COSV100135460; called by muse, mutect2, varscan2
- GARNL3 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100150477; called by muse, mutect2, varscan2
- GAS8 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs374824417; called by muse, mutect2, varscan2
- GATA3 | c.333del p.W112Gfs*83 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as COSV60517130; called by mutect2, pindel, varscan2
- GBF1 | c.2426G>A p.R809H (on ENST00000369983 / NM_001377137.1; = p.R808H on NM_004193.3) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143973197, COSV64142863; called by muse, mutect2, varscan2
- GBP1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs748915855, COSV100976281; called by muse, mutect2, varscan2
- GBP6 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as COSV100969583, COSV99059839; called by muse, mutect2, varscan2
- GCN1 | c.2948C>T p.P983L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100325559; called by muse, mutect2, varscan2
- GDI2 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66335792; called by muse, mutect2, varscan2
- GFPT1 | c.1349G>A p.G450D (on ENST00000357308 / NM_001244710.2; = p.G432D on NM_002056.4) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100622889; called by muse, mutect2, varscan2
- GFRA1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62602664; called by muse, mutect2
- GGA3 | c.1741C>A p.L581M (on ENST00000537686 / NM_138619.4; = p.L548M on NM_014001.5) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99822152; called by muse, mutect2, varscan2
- GGCX | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs1271782787, COSV52089896; called by muse, mutect2, varscan2
- GIMAP8 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs200592029, COSV56232852, COSV56235726; called by muse, mutect2, varscan2
- GJA8 | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV99569263, COSV99569526; called by muse, mutect2, varscan2
- GLB1L2 | c.1472T>A p.V491D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100335412; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLO1 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974100; called by muse, mutect2, varscan2
- GLRA1 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as rs1296531416, COSV51016071; called by muse, mutect2, varscan2
- GLRA3 | c.661C>A p.L221M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.436); catalogued as COSV56871076, COSV99927578; called by muse, mutect2, varscan2
- GNAI3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 17/89 reads (19%) | catalogued as rs766202043, COSV63983494; called by muse, mutect2, varscan2
- GNB4 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV99224361; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNG13 | c.166_168del p.N56del | In Frame Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs754937972; called by pindel, varscan2
- GOLGA2 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57854444; called by muse, mutect2, varscan2
- GOLGA3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs201001117; called by muse, mutect2, varscan2
- GOLGA6A | c.151dup p.T51Nfs*2 | Frame Shift Ins (INS) | VAF 44/146 reads (30%) | catalogued as rs764754072; called by mutect2, varscan2
- GOLGB1 | c.8344_8345dup p.D2782Efs*12 | Frame Shift Ins (INS) | VAF 23/62 reads (37%) | catalogued as rs747719358; called by mutect2, varscan2
- GOLM1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780788709, COSV99974419; called by muse, mutect2, varscan2
- GON4L | c.2094C>T p.H698= | Splice Region (SNP) | VAF 17/87 reads (20%) | catalogued as rs191702841, COSV55200807; called by muse, mutect2, varscan2
- GPAT4 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV67842129; called by muse, mutect2, varscan2
- GPATCH2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs867427900, COSV100861400; called by muse, mutect2, varscan2
- GPN2 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs773359763, COSV64651569; called by muse, mutect2, varscan2
- GPR156 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100251514; called by muse, mutect2, varscan2
- GPR182 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV100267759; called by muse, mutect2, varscan2
- GPR39 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.916); catalogued as COSV100258012; called by muse, mutect2, varscan2
- GPR4 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.145); catalogued as rs1386058464, COSV59917929; called by muse, mutect2, varscan2
- GPRC5B | c.751A>G p.M251V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100315190; called by muse, mutect2
- GPX3 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs560735748, COSV59309490; called by muse, mutect2, varscan2
- GRB10 | c.1678G>A p.G560R (on ENST00000398812; = p.G514R on NM_001001549.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208311662, COSV60014686; called by muse, mutect2, varscan2
- GREM2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV58947365; called by muse, mutect2, varscan2
- GRIA2 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1276241823, COSV52382522; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs754199513; called by mutect2, varscan2
- GSN | c.437A>G p.H146R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58000213; called by muse, mutect2
- GTF2IRD1 | c.2644G>A p.A882T (on ENST00000265755 / NM_016328.3; = p.A867T on NM_005685.4) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99734968; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel
- H1-6 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1183389747, COSV100619592, COSV58090954; called by muse, mutect2, varscan2
- H2BC8 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as rs1448089436, COSV55127544; called by muse, mutect2, varscan2
- H3-5 | c.315A>C p.E105D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100461699; called by muse, mutect2, varscan2
- HACD1 | c.618del p.F206Lfs*23 | Frame Shift Del (DEL) | VAF 54/132 reads (41%) | catalogued as rs1564504589; called by mutect2, pindel, varscan2
- HACD4 | c.118G>T p.V40F | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV101529960; called by muse, mutect2, varscan2
- HAPLN4 | c.705del p.T236Pfs*43 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV52270379; called by mutect2, varscan2
- HAUS4 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs757985683, COSV99246986; called by mutect2, varscan2
- HAUS6 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs747156587, COSV100787220; called by muse, varscan2
- HBM | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs370295970; called by muse, mutect2, varscan2
- HDAC3 | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99781424; called by muse, mutect2, varscan2
- HDLBP | c.2108G>T p.R703M | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100191184; called by muse, mutect2, varscan2
- HEATR1 | c.4561A>G p.M1521V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV100857699; called by muse, mutect2, varscan2
- HEATR3 | c.526A>G p.R176G | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV99590005; called by muse, mutect2, varscan2
- HEATR5B | c.6214del p.*2072Nfs*3 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs1315552549, COSV51848615; called by mutect2, varscan2
- HECA | c.1004del p.G335Dfs*27 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs771658394; called by mutect2, pindel, varscan2
- HECTD4 | c.5893C>A p.L1965I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.997); catalogued as COSV66397551; called by muse, mutect2, varscan2
- HECW2 | c.4354G>T p.G1452C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647747; called by muse, mutect2, varscan2
- HECW2 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as COSV99647749; called by muse, mutect2, varscan2
- HELB | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1441595966, COSV99922017; called by muse, mutect2, varscan2
- HELZ2 | c.6616del p.R2206Vfs*29 (on ENST00000467148 / NM_001037335.2; = p.R1637Vfs*29 on NM_033405.3) | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs745497383, COSV101427649; called by mutect2, varscan2
- HELZ2 | c.3935A>G p.D1312G (on ENST00000467148 / NM_001037335.2; = p.D743G on NM_033405.3) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1312070738, COSV101427585; called by muse, mutect2, varscan2
- HENMT1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs985573606, COSV64230594; called by muse, mutect2, varscan2
- HERC1 | c.7237C>T p.R2413* | Nonsense Mutation (SNP) | VAF 11/161 reads (7%) | catalogued as rs1452104180, COSV71246582, COSV71248095; called by muse, mutect2
- HERC2 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs367923183; called by muse, varscan2
- HEXB | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as COSV99714493; called by muse, mutect2
- HHAT | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99805031; called by muse, mutect2
- HID1 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV59352557; called by muse, mutect2, varscan2
- HINFP | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs558542812, COSV100640812, COSV63431974; called by muse, mutect2, varscan2
- HIP1 | c.371T>C p.M124T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.898); catalogued as COSV100417765; called by muse, mutect2, varscan2
- HIPK2 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV69207878; called by muse, mutect2, varscan2
- HIVEP2 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); catalogued as COSV99174236; called by muse, mutect2, varscan2
- HK2 | c.2078T>C p.V693A | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99309277; called by muse, mutect2, varscan2
- HLA-B | c.1012+2T>C p.X338_splice | Splice Site (SNP) | VAF 25/53 reads (47%) | catalogued as rs1476457470, COSV69520414; called by muse, mutect2, varscan2
- HLA-DOA | c.422del p.P141Lfs*2 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as rs764712484; called by mutect2, pindel, varscan2
- HLF | c.297del p.S100Afs*106 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as COSV56830780; called by mutect2, pindel, varscan2
- HMGN3 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV99245657; called by muse, mutect2, varscan2
- HMX2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV100378723; called by muse, mutect2, varscan2
- HNRNPK | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100699069; called by muse, mutect2, varscan2
- HNRNPL | c.1002del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as COSV99670288; called by mutect2, pindel, varscan2
- HRG | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99214893; called by muse, mutect2, varscan2
- HSD17B12 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV99550814; called by muse, mutect2, varscan2
- HYDIN | c.6487G>A p.G2163R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.856); catalogued as rs201229133, COSV99993208; called by mutect2, varscan2
- HYPK | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99979962; called by muse, mutect2
- ICAM5 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs765026177, COSV55747572; called by mutect2, varscan2
- IFI16 | c.*2del | Frame Shift Del (DEL) | VAF 33/127 reads (26%) | catalogued as rs757602743, COSV55540908; called by mutect2, pindel, varscan2
- IFT140 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101276502; called by muse, mutect2, varscan2
- IFT46 | c.571C>T p.R191C (on ENST00000264021 / NM_001168618.2; = p.R242C on NM_020153.3) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782595984, COSV50594348; called by muse, mutect2, varscan2
- IFT74 | c.404G>T p.R135M | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV66288288; called by muse, mutect2, varscan2
- IGF1R | c.2398C>T p.R800C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1318014146, COSV99153072; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs760021495; called by mutect2, varscan2
- IGHA1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759216050; called by muse, mutect2, varscan2
- IGHA2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782085693; called by muse, mutect2, varscan2
- IGHV3-7 | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as rs113165346; called by muse, mutect2, varscan2
- IGSF5 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.223); catalogued as COSV101012094, COSV66030549; called by muse, mutect2, varscan2
- IL17RB | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs61751221; called by muse, varscan2
- IL17REL | c.213dup p.Q72Afs*118 | Frame Shift Ins (INS) | VAF 8/9 reads (89%) | catalogued as rs747097955; called by mutect2, varscan2
- IL18RAP | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99962170; called by muse, mutect2, varscan2
- IL1R1 | c.989C>A p.P330Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV52106197, COSV99292705; called by muse, mutect2
- IL37 | c.188A>G p.H63R | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99636313; called by muse, mutect2, varscan2
- IL4I1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99680787; called by muse, mutect2, varscan2
- IL6ST | c.1172T>A p.L391H | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV61142522; called by muse, mutect2, varscan2
- IMMT | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756459398, COSV99607079; called by muse, mutect2, varscan2
- IMPA1 | c.303-2dup p.X101_splice | Splice Site (INS) | VAF 28/84 reads (33%) | catalogued as rs763126450; called by mutect2, varscan2
- INAVA | c.1529del p.L510Hfs*62 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as COSV66257298; called by mutect2, pindel
- INHA | c.197del p.G66Afs*61 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs1190141661; called by mutect2, pindel, varscan2
- INHBA | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54226746; called by muse, mutect2
- INSM2 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99355322; called by muse, mutect2, varscan2
- INTS1 | c.5099C>T p.A1700V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as rs1236304131, COSV101248110; called by muse, mutect2, varscan2
- INTS1 | c.3635C>T p.A1212V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV67179633; called by muse, mutect2, varscan2
- INTS11 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs752783300, COSV100028467; called by muse, mutect2, varscan2
- INTS6L | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV66085661; called by muse, mutect2
- IP6K1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150703602; called by muse, mutect2, varscan2
- IPPK | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55334535; called by muse, mutect2
- IQCA1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1364050704, COSV54509923; called by muse, mutect2, varscan2
- IQCH | c.2273A>G p.D758G | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100246041; called by muse, mutect2, varscan2
- IQSEC1 | c.779G>A p.C260Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99832070; called by muse, mutect2, varscan2
- IRS2 | c.2272G>T p.G758C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV101019232; called by muse, mutect2, varscan2
- IRX2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57411026; called by muse, mutect2, varscan2
- ITGA1 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1381525453, COSV50884928; called by muse, mutect2, varscan2
- ITGA11 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1416567694, COSV100241839; called by muse, mutect2, varscan2
- ITGAX | c.2570G>A p.G857D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.087); catalogued as rs1391799988, COSV99191870; called by muse, mutect2, varscan2
- ITGB2 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs756545465, COSV56615319; called by muse, mutect2, varscan2
- ITGB4 | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs913526266, COSV52331082; called by muse, mutect2, varscan2
- ITGB5 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776835945, COSV56146846, COSV56148331; called by muse, mutect2, varscan2
- ITGB5 | c.431T>C p.M144T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99950853; called by muse, mutect2, varscan2
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | catalogued as rs760028800; called by mutect2, varscan2
- ITIH1 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.915); catalogued as rs1197545618, COSV56256169; called by muse, mutect2, varscan2
- ITSN1 | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); catalogued as rs772592802, COSV101180589; called by muse, mutect2, varscan2
- JAG2 | c.2220del p.G741Afs*21 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1555369773; called by mutect2, pindel
- JAK3 | c.2836G>A p.V946M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1417829450, COSV71686002; called by muse, mutect2, varscan2
- JARID2 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs371399734; called by muse, mutect2, varscan2
- JARID2 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs751363793, COSV100522024; called by muse, mutect2, varscan2
- JOSD1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99322692; called by muse, mutect2
- JPH1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60609005; called by muse, mutect2, varscan2
- JPH3 | c.1060del p.L354Cfs*117 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV52470301; called by mutect2, pindel, varscan2
- JUP | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.2); catalogued as COSV100159363, COSV100159666; called by muse, mutect2, varscan2
- KANK1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1233482200; called by muse, mutect2
- KANK1 | c.3404T>C p.M1135T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.119); catalogued as rs778303097, COSV63214438; called by muse, mutect2, varscan2
- KAT6A | c.4679C>T p.T1560I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705418; called by muse, mutect2, varscan2
- KCNC3 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65389071; called by muse, mutect2, varscan2
- KCNF1 | c.1225T>G p.F409V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54465040; called by muse, mutect2, varscan2
- KCNH6 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs773344095, COSV59006670; called by muse, mutect2, varscan2
- KCNH6 | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV59006680; called by muse, mutect2, varscan2
- KCNH8 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs757153750, COSV100110320; called by muse, mutect2, varscan2
- KCNJ5 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100610740; called by muse, mutect2, varscan2
- KCNMA1 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54275686; called by muse, mutect2
- KCNQ1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs543428644, COSV50100114; ClinVar: uncertain significance; called by muse, varscan2
- KCNQ3 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV101196243; called by muse, mutect2, varscan2
- KCNQ5 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV59661938; called by muse, mutect2, varscan2
- KCNQ5 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1390470611, COSV59684254; called by muse, mutect2, varscan2
- KCNS2 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as COSV54641483, COSV99751282; called by muse, mutect2
- KCTD10 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.262); catalogued as rs200831911, COSV57328020, COSV99949485; called by muse, mutect2, varscan2
- KCTD13 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV58161203; called by muse, mutect2, varscan2
- KCTD2 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs763352643, COSV100483343; called by muse, mutect2, varscan2
- KDF1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762329870, COSV100264563; called by muse, mutect2, varscan2
- KDF1 | c.408dup p.S137Qfs*3 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | catalogued as rs752617278; called by mutect2, pindel, varscan2
- KDM2B | c.77dup p.K27Efs*10 | Frame Shift Ins (INS) | VAF 24/85 reads (28%) | catalogued as rs782541016; called by mutect2, varscan2
- KDM4A | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs369667794, COSV64960446; called by muse, mutect2, varscan2
- KDM4B | c.435C>T p.D145= | Splice Region (SNP) | VAF 10/18 reads (56%) | catalogued as rs771412550, COSV99346781; called by muse, mutect2, varscan2
- KDM4B | c.1541C>A p.P514H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294034610, COSV50246050; called by muse, mutect2, varscan2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 44/73 reads (60%) | catalogued as rs747555402; called by mutect2, pindel, varscan2
- KEAP1 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.489); catalogued as COSV99407988; called by muse, mutect2, varscan2
- KIAA1217 | c.2642G>A p.G881D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.221); catalogued as COSV100286871; called by muse, mutect2
- KIAA1549 | c.848del p.L283* | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as rs752375544, COSV54318481; called by mutect2, varscan2
- KIAA1586 | c.619del p.I207Lfs*17 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs746314511; called by mutect2, varscan2
- KIF13B | c.4726G>A p.A1576T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV101342275; called by mutect2, varscan2
- KIF14 | c.1608-1G>A p.X536_splice | Splice Site (SNP) | VAF 37/147 reads (25%) | catalogued as COSV100950951; called by muse, mutect2, varscan2
- KIF14 | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as rs780290398, COSV100950952; called by muse, mutect2, varscan2
- KIF21A | c.4622del p.P1541Lfs*6 (on ENST00000361418 / NM_001378440.1; = p.P1528Lfs*6 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as COSV62771708; called by mutect2, pindel, varscan2
- KIF21B | c.3734G>A p.R1245Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as rs757271782, COSV59760963; called by muse, mutect2, varscan2
- KIF26A | c.4556C>T p.T1519M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs552359730, COSV59466307; called by muse, varscan2
- KIF26B | c.5008G>A p.G1670S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63648835; called by muse, mutect2
- KIF27 | c.2596dup p.R866Kfs*9 | Frame Shift Ins (INS) | VAF 68/326 reads (21%) | catalogued as rs777107884; called by pindel, varscan2
- KIF2A | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101136536; called by muse, mutect2, varscan2
- KIF3C | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53101324, COSV99267599; called by muse, mutect2, varscan2
- KIFBP | c.767T>C p.L256S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1177613996, COSV62832286; called by muse, mutect2, varscan2
- KIFC2 | c.1040G>A p.C347Y | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.087); catalogued as COSV100023883; called by muse, mutect2, varscan2
- KIFC2 | c.1714C>A p.L572M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs747400205, COSV100023884; called by muse, mutect2, varscan2
- KIRREL1 | c.1009del p.L337Sfs*14 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs754171400, COSV63285253; called by mutect2, pindel, varscan2
- KLF12 | c.1156T>G p.F386V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100888542; called by muse, mutect2, varscan2
- KLHL22 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338267056, COSV61020376; called by muse, mutect2
- KLHL23 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs1322865156, COSV55866799; called by muse, mutect2, varscan2
- KLHL40 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99825621; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as COSV52930337; called by mutect2, varscan2
- KLHL6 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100384822; called by muse, mutect2, varscan2
- KLKB1 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs1372696539, COSV99250160; called by muse, mutect2, varscan2
- KLRC1 | c.675A>G p.I225M | Missense Mutation (SNP) | VAF 142/492 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs139182795, COSV61725770; called by muse, varscan2
- KMT2B | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1250203458, COSV99386146; called by muse, mutect2, varscan2
- KMT2B | c.7660C>T p.R2554C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99495234; called by muse, mutect2, varscan2
- KMT2C | c.13622G>A p.R4541Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs754423379, COSV100073810; called by mutect2, varscan2
- KMT2C | c.838G>T p.G280W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100073813; called by muse, mutect2, varscan2
- KMT2D | c.11857C>T p.Q3953* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99983643; called by muse, mutect2, varscan2
- KRT10 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99510142; called by muse, mutect2, varscan2
- KRT222 | c.485del p.K162Sfs*16 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as COSV67497872, COSV67498194; called by mutect2, pindel, varscan2
- KRT3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs772879943, COSV58814764; called by muse, mutect2, varscan2
- KRT40 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs200561810; called by muse, mutect2, varscan2
- KRT6B | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV99360839; called by muse, mutect2, varscan2
- KRT6C | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs779662593, COSV99359879; called by muse, mutect2, varscan2
- KRTAP10-6 | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV100554422; called by muse, mutect2, varscan2
- KRTAP13-3 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV61880967; called by mutect2, varscan2
- KRTAP17-1 | c.218del p.G73Vfs*41 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | catalogued as rs1467971322; called by mutect2, pindel, varscan2
- KRTAP24-1 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV61089978; called by muse, mutect2, varscan2
1,842 further variants in this file (1,203 protein-altering or splice-affecting, 591 silent, 48 other) are not listed here.
